Somatic mutation profile of tumor specimen TARGET-30-PATVDY-09A (aliquot TARGET-30-PATVDY-09A-01D) from TARGET case TARGET-30-PATVDY, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 3.4 years (1,248 days).
Specimen TARGET-30-PATVDY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6454e130-85c3-4d1a-aaa9-b102a98926d9.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATVDY-10A (Blood Derived Normal), aliquot TARGET-30-PATVDY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c8088f6-0222-4ef6-a419-839b7b99b2a6

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SGCA | c.380C>A p.P127Q | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs777028657; called by mutect2, varscan2
